Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0AT, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0AT-TTP1-A (Primary Tumor).

[page 1 of 19]
TO
PHYSICIAN

FROM

DATE-TIME OF REQUEST/REPORT

PRIORITY

TRANSPORT

PATHOLOGY-SURGICAL

SURGICAL PATHOLOGY

- (1) ESOPHAGEAL BIOPSY, RULE OUT BARRETT'S
- (2) ESOPHAGEAL BIOPSY, PROBABLE CA

CLINICAL INFORMATION:

Abdominal pain, bloating

PROCEDURE: EGD

DIAGNOSIS

- 1. Esophageal biopsy:
- Adenocarcinoma
- Associated Barrett's esophagitis
- 2. Esophageal biopsy:
- Adenocarcinoma, moderately to poorly differentiated
- Extensive necrosis, inflammation, erosion, and ulceration

GROSS PATHOLOGY:

Specimen #1 consists of four tannish-brown fragments each 1.0 to 2.0 mm, fixed in formalin and submitted in toto.

Specimen #2 consists of six tannish-brown fragments measuring from 1.0 to 2.0 mm, fixed in formalin and submitted in toto.

+0

MICROSCOPIC PATHOLOGY:

Specimen #1 shows stratified squamous epithelium. There are sections with gastric glands. In the gastric glands, there are areas with intestinal goblet cell metaplasia. There are other glands that are crowded. They are lined by columnar cells. The columnar cells are highly pleomorphic. They have hyperchromatic nuclei. Mitotic figures are seen. It is admixed with inflammation.

*** T E M P O R A R Y R E S U L T ***

NOTE: This report is confidential, intended only for use in the care and treatment of the patient, and shall not be disclosed to any other person or used for any other purpose.

[page 2 of 19]
PAGE: 2

DATE-TIME OF REQUEST/REPORT	PRIORITY	TRANSPORT
+0		

PATHOLOGY-SURGICAL

Specimen #2 shows sections with stratified squamous epithelium. There is necrotic debris. There is tumor. The tumor has gland configuration. The glands are embedded within a fibrohyalinized stroma. There is a pseudostratified layer of columnar cells. They are highly pleomorphic. They have hyperchromatic nuclei. There is associated acute and chronic inflammation. One or two areas suggest slight papillary configuration.

*** T E M P O R A R Y R E S U L T ***

NOTE: This report is confidential, intended only for use in the care and treatment of the patient, and shall not be disclosed to any other person or used for any other purpose.

[page 3 of 19]
Final Report

P
A
T
I
E
N
T

DOB: [REDACTED]
Surgical: [REDACTED]
Patient ID: [REDACTED]
Address: [REDACTED]
Phone: [REDACTED]

S
A
M
P
L
E

Specimen ID: [REDACTED]
Date of Report: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Source: Esophageal biopsy
Clinical Information: Fixation time not provided
Abdominal pain bloating

+38
+0
+35

AUTOMATED HER-2/NEU FISH ANALYSIS FOR GASTRIC/ESOPHAGEAL ADENOCARCINOMA

Test Description	Interpretation and Results	Photomicrograph
HER2 FISH	Positive/Amplified HER2 : CEP-17 ratio: 7.3:1 Average HER2 Signal: 18.4 Maximum HER2 Signal: 30.4 Average CEP-17 Signal: 2.5 Number of Tiles Scanned: 402 Hyperdiploid	 Note relative predominance of red (HER2) signals compared to green (CEP-17) signals (x1000).

INTERPRETIVE INFORMATION

HER-2/neu FISH results are best interpreted by analyzing the ratio with respect to the HER-2/neu copy number. An H & E slide was reviewed and demonstrates lesional tissue. Analysis of HER-2/neu gene amplification status was performed using an automated Fluorescence In Situ Hybridization (FISH) signal enumeration system ([REDACTED] Watertown, MA). This system scans up to 5 different specified areas of tumor; a tile is generally equivalent to 1 cell.

The following interpretive guidelines are derived from the references below. They vary slightly from CAP/ASCO HER2 guidelines for breast cancer. In [REDACTED] CAP issued the following statement regarding gastric HER2 testing: "Although there is some evidence that HER2 IHC may, in some circumstances, be more predictive than FISH, the current recommendations for HER2 FISH testing in gastric cancer are the same as those for breast cancer. That is, FISH testing should be performed when the IHC is equivocal (2+)." Cutoff criteria for interpretation were not included in this statement.

* Negative/Not amplified: A ratio of <2:1 with an average HER-2 signal count of 4 or more copies/cell, or any ratio with an average HER-2 signal count of <4 copies/cell is considered negative/not amplified.

* Positive/Amplified: Results ≥ 2.0 with an average HER-2 signal count of >4 copies/cell, or any ratio with an average HER-2 signal count of ≥ 7 .

REFERENCES

1. Bang, Y-J, Van Cutsem E, Feyereislova A, et al. Trastuzumab in combination with chemotherapy versus chemotherapy alone for treatment of HER-2-positive advanced gastric or gastro-oesophageal junction cancer (ToGA): a phase 3, open-label, randomised controlled trial. Lancet 376(9742):687-97, 2010.
2. Hofmann M, Stoss O, Buttnar R, et al. Assessment of a HER-2 scoring system for gastric cancer: results from a validation study. Histopathology 52(7):797-805, 2008.

[REDACTED] HER-2/neu DNA probe kit (Vysis) was used. This test was developed and its performance characteristics determined by Vysis. This lab has been approved by CLIA 88, designated as a high complexity laboratory and is qualified to perform these tests. Results are reported using the ASCO/CAP scoring criteria.

[page 4 of 19]
CT Chest WITH contrast

Order # [REDACTED]

Reason For Exam

EVAL FOR ADVANCED NEOPLASM,LYMPHOMA

Interpretation Summary

CT scan of the thorax.

Date: [REDACTED] +0

Comparison: None.

History: Lymphoma.

Technique: Helical scan of the thorax was performed following intravenous contrast enhancement.

Findings: The axillary regions are normal. There is adenopathy beginning in the thoracic inlet slightly to the left of midline and posterior to the brachiocephalic vein. A lymph node in this region measures up to 2.4 cm with additional adenopathy identified in the prevascular space with nodes measuring up to 15 mm. Granulomatous calcifications are present in the mediastinum. The precarinal and subcarinal spaces appear normal. The cardiac chambers are normal. The liver and spleen have a normal and uniform enhancement. The gallbladder, stomach, pancreas, adrenals and upper poles of the kidneys are normal. Retroperitoneal adenopathy is identified on the last few images, but incompletely characterized on this study.

Evaluation of the thoracic spine demonstrates minor endplate degenerative changes. No lytic or blastic lesions or acute displaced rib fractures are present.

Evaluation of the lung parenchyma does not demonstrate any suspicious pulmonary nodules; granulomatous calcifications are present. No pleural fluid or pneumothorax is present.

Impression: Patient has a history of lymphoma. There are abnormal lymph nodes identified at the thoracic inlet to the left of midline, adjacent to the left brachiocephalic vein and extending into the prevascular space. The patient is

[page 5 of 19]
known to have extensive retroperitoneal adenopathy in the abdomen and this likely represents thoracic spread of disease.

Old granulomatous disease.

PACS Images

Show images for CT Chest WITH contrast

Study Result

CT scan of the thorax.

Date [REDACTED] +0

Comparison: None.

History: Lymphoma.

Technique: Helical scan of the thorax was performed following intravenous contrast enhancement.

Findings: The axillary regions are normal. There is adenopathy beginning in the thoracic inlet slightly to the left of midline and posterior to the brachiocephalic vein. A lymph node in this region measures up to 2.4 cm with additional adenopathy identified in the prevascular space with nodes measuring up to 15 mm. Granulomatous calcifications are present in the mediastinum. The precarinal and subcarinal spaces appear normal. The cardiac chambers are normal. The liver and spleen have a normal and uniform enhancement. The gallbladder, stomach, pancreas, adrenals and upper poles of the kidneys are normal. Retroperitoneal adenopathy is identified on the last few images, but incompletely characterized on this study.

Evaluation of the thoracic spine demonstrates minor endplate degenerative changes. No lytic or blastic lesions or acute displaced rib fractures are present.

Evaluation of the lung parenchyma does not demonstrate any suspicious pulmonary nodules; granulomatous calcifications are present. No pleural fluid or pneumothorax is present.

Impression: Patient has a history of lymphoma. There are abnormal lymph nodes identified at the thoracic inlet to the left of midline, adjacent to the left brachiocephalic vein and extending into the prevascular space. The

[page 6 of 19]
[REDACTED]

patient is
known to have extensive retroperitoneal adenopathy in the abdomen and
this
likely represents thoracic spread of disease.

Old granulomatous disease.

[REDACTED]

Order Report

CT Chest WITH contrast (Order [REDACTED] on [REDACTED]
[REDACTED] +0

Reprint Order Requisition

CT Chest WITH contrast (Order [REDACTED] on [REDACTED]
[REDACTED] +0

PACS Images

Show images for CT Chest WITH contrast

[REDACTED]

[page 7 of 19]
CT Abdomen pelvis WITH and withOUT contrast

Reason For Exam

abd and rectal pain/PRESSURE

Interpretation Summary

Exam: CT abdomen and pelvis with contrast.

History: Abdominal and rectal pain. Pressure. Comparison none.

Technique: Transaxial CT performed lung bases through the adrenal glands after oral contrast. Repeat imaging obtained lung bases through the pubic symphysis after intravenous contrast. Delayed imaging through the bladder.

Findings: Visualized portions of the lung bases show a 3 mm noncalcified indeterminate pulmonary nodule right lower lobe at the base. Bone window imaging shows no lytic or blastic lesions. Calcified granulomatous disease right hilum.

No focal hepatic lesion identified. Gallbladder within normal limit in appearance. Spleen of normal size. Pancreas within normal limit in morphology.

Both adrenal glands within normal limit in appearance. Both kidneys show

symmetric enhancement without hydronephrosis. Contrast excretion within the

bladder on delayed imaging. Prostate within normal limit in size.

Abdominal aorta within normal limit in caliber. There is extensive conglomerate retroperitoneal lymphadenopathy. This is seen aortocaval as well as left periaortic.

No small bowel obstruction. Some scattered less than 1 cm short axis groin lymph nodes.

Impression:

1. Extensive conglomerate retroperitoneal lymphadenopathy.

Differential

diagnoses might include metastatic disease or lymphoma.

2. No free intraabdominal air. No free fluid in the pelvis. No bowel obstruction.

3. No hydronephrosis.

PACS Images

Show images for CT Abdomen pelvis WITH and withOUT contrast

Study Result

[page 8 of 19]
Exam: CT abdomen and pelvis with contrast.

History: Abdominal and rectal pain. Pressure. Comparison none.

Technique: Transaxial CT performed lung bases through the adrenal glands after oral contrast. Repeat imaging obtained lung bases through the pubic symphysis after intravenous contrast. Delayed imaging through the bladder.

Findings: Visualized portions of the lung bases show a 3 mm noncalcified indeterminate pulmonary nodule right lower lobe at the base. Bone window imaging shows no lytic or blastic lesions. Calcified granulomatous disease right hilum.

No focal hepatic lesion identified. Gallbladder within normal limit in appearance. Spleen of normal size. Pancreas within normal limit in morphology. Both adrenal glands within normal limit in appearance. Both kidneys show symmetric enhancement without hydronephrosis. Contrast excretion within the bladder on delayed imaging. Prostate within normal limit in size.

Abdominal aorta within normal limit in caliber. There is extensive conglomerate retroperitoneal lymphadenopathy. This is seen aortocaval as well as left periaortic.

No small bowel obstruction. Some scattered less than 1 cm short axis groin lymph nodes.

Impression:

1. Extensive conglomerate retroperitoneal lymphadenopathy. Differential diagnoses might include metastatic disease or lymphoma.
2. No free intraabdominal air. No free fluid in the pelvis. No bowel obstruction.
3. No hydronephrosis.

Signed by

Signed	Date/Time	Phone	Pager

Exam Information

-6

Status	Exam Begun	Exam Ended

External Results Report

-7

Encounter

-7

Open External Results Report

View Encounter

Order Report

Reprint Order Requisition

[page 9 of 19]
[REDACTED]
CT Abdomen pelvis WITH and withOUT contrast

-7

CT Abdomen pelvis WITH and withOUT contrast

-7

PACS Images

Show images for CT Abdomen pelvis WITH and withOUT contrast

[page 10 of 19]
Patient: [REDACTED]

DOB: [REDACTED]

Observation Date: [REDACTED]

EXAM: Whole-body PET CT scan.

HISTORY: Esophageal cancer.

COMPARISON: None of this type.

PROCEDURE: The patient was injected with 14.46 millicuries of F-18 FDG and allowed to rest in a quiet room for approximately 1 hour. The patient was then placed on the scanning table and a whole body scan performed from the skull base through the level of the pubic symphysis in conjunction with a spiral CT scan from the skull base through the pubic symphysis utilized both for attenuation correction and also for the creation of a spatially registered CT examination for PET / CT fusion. The CT scan, PET scan and fused PET/CT scan were presented for evaluation in axial, sagittal and coronal planes. Additional images including a rotating maximum intensity projection image of the PET scan were provided as required. (The noncontrast CT images utilized for fusion with the PET images to create the PET / CT images are not of diagnostic quality and are not used to diagnose disease independently of the PET images.) The patient's blood glucose level was 85 milligrams per deciliter.

FINDINGS:

In the head and neck, the included portions of the orbits and paranasal sinuses demonstrate normal levels of activity. The nasopharynx, oropharynx and oral cavity demonstrate elevated but presumably physiologic/inflammatory levels of activity. The larynx and vocal cords demonstrate normal activity. The salivary glands demonstrate normal levels of activity. The thyroid gland demonstrates normal levels of activity. No FDG avid lymph nodes are seen in the neck.

In the thorax, the lungs are well expanded with no evidence of acute infiltrate, consolidation or effusion. No FDG avid nodules are seen within the lung fields. The examination demonstrates increased uptake of FDG in the infracarinal portion of the esophagus with SUV max of 17.1. This occurs in two discrete foci, the greater activity in the more distal. Examination additionally demonstrates a conglomerate mass of periaortic adenopathy on the left extending from the level of the apex to the level of the left pulmonary artery with SUV max of

[page 11 of 19]
25.6. The heart is normal in size. The thoracic aorta is normal in caliber. There is evidence of calcified nodes in the hila and mediastinum. There is nonuniform mildly increased physiologic uptake of FDG within the left ventricular myocardium.

In the abdomen and pelvis, the liver demonstrates a typical heterogeneous pattern of activity. The representative SUV max in the liver is approximately 4.4. The spleen is normal in appearance. The stomach is physiologically distended and demonstrates modest diffusely increased uptake of FDG with SUV max of 11.5. There is preaortic adenopathy at the level of the diaphragmatic crura with SUV max of 42.7. Immediately below this, there is retrocrural periaortic adenopathy with SUV max of 15.6. The pancreas demonstrates a linear region of increased activity along its inferior margin from the body to the tail with SUV max of 7.9. This may represent adjacent adenopathy rather than an intrinsic lesion. There is a second cluster of right retrocrural periaortic adenopathy with SUV max of 14.2 below the first and below this, a third cluster of retroaortic adenopathy with SUV max of 27.9. At the level of the bifurcation, there is a more massive cluster of adenopathy which extends along the iliac origins (left more than right) with SUV max of 19.4. Additional left peri-iliac nodes demonstrate SUV max of 25.9. The adrenal glands demonstrate normal levels of activity. The gallbladder is normally distended and contains no identifiable stones. The kidneys, ureters and urinary bladder demonstrate physiologic levels of activity. The abdominal aorta is normal in caliber. There is no evidence of ascites or pneumoperitoneum. Activity within the small bowel is within normal limits. The colon demonstrates regions of increased activity particularly in the hepatic flexure, probably physiologic.

The included portions of the skeleton demonstrate normal physiologic levels of activity.

IMPRESSION:

1. The PET CT examination demonstrates two major foci of increased activity in the distal esophagus, compatible with the patient's diagnosis of esophageal cancer. Details are provided in the body of the report. The examination additionally demonstrates conglomerate adenopathy in a left periaortic mediastinal mass extending from the lung apex to the level of the pulmonary artery. No discrete pulmonary metastases are identified.
2. In the abdomen and pelvis, the examination demonstrates multiple periaortic lymph nodes with markedly increased uptake of FDG

[page 12 of 19]
extending from the level of the diaphragmatic crura through and below the level of the bifurcation, details provided in the body of the report. The examination also demonstrates a linear collection of increased activity along the inferior margin of the body and tail of the pancreas. It is not possible to differentiate between intrinsic pathologic lesions and adjacent adenopathy; however, the latter is favored.

3. The examination demonstrates modest increased activity in the region of the hepatic flexure of the colon, probably physiologic.
4. The examination demonstrates normal levels of activity in the included portions of the skeleton.
5. The examination demonstrates normal levels of activity in the included portions of the head and neck.

[page 13 of 19]
PET Esophageal cancer restaging

Reason For Exam

MALIGNANT NEOPLASM OF LOWER THIRD OF ESOPHAGUS

Interpretation Summary

EXAM: Whole-body PET CT scan. +0

HISTORY: Esophageal cancer diagnosed in [REDACTED] Restaging.

COMPARISON: [REDACTED] +28

PROCEDURE: The patient was injected with 14.4 millicuries of F-18 FDG and allowed to rest in a quiet room for approximately 1 hour. The patient was then placed on the scanning table and a whole body scan performed from the skull base through the level of the thighs in conjunction with a spiral CT scan from the skull base through the level of the thighs utilized both for attenuation correction and also for the creation of a spatially registered CT examination for PET / CT fusion. The CT scan, PET scan and fused PET/CT scan were presented for evaluation in axial, sagittal and coronal planes. Additional images including a rotating maximum intensity projection image of the PET scan were provided as required. (The noncontrast CT images utilized for fusion with the PET images to create the PET / CT images are not of diagnostic quality and are not used to diagnose disease independently of the PET images.) The patient's blood glucose level was 88 milligrams per deciliter.

FINDINGS:

In the head and neck, the included portions of the orbits and paranasal sinuses demonstrate normal levels of activity. The nasopharynx, oropharynx and oral cavity demonstrate normal levels of activity. The larynx and vocal cords demonstrate normal levels of activity. The salivary glands demonstrate normal levels of activity. The thyroid gland demonstrates normal levels of activity. No FDG avid lymph nodes are seen in the neck. There is a chemotherapy infusion port implanted in the right anterior chest wall with subclavian catheter extending into the superior vena cava terminating above the cavoatrial junction.

In the thorax, the lungs are generally well expanded with no evidence of significant infiltrate or consolidation or effusion. No significantly FDG avid nodules are seen within the lung fields. The extensive highly FDG avid adenopathy seen on the prior examination is absent on the current examination. There are calcified nodes in the right hilar region and a few calcified pulmonary nodules compatible with granulomatous disease. The thoracic aorta is normal in caliber. There is no detectable vascular calcification. The heart is normal in size. There is moderately extensive physiologic uptake of FDG within the left ventricular myocardium. There is no significantly elevated activity in the esophagus on the current examination.

In the abdomen and pelvis, the liver demonstrates a typical

[page 14 of 19]
heterogeneous pattern of activity. The representative SUV max for the liver is 4.2. The spleen is normal in appearance. The stomach is physiologically distended with ingested material and demonstrates normal levels of activity. The pancreas demonstrates normal levels of activity. The adrenal glands demonstrate normal levels of activity. The gallbladder is normally distended and contains no identifiable stones. The kidneys, ureters and urinary bladder demonstrate physiologic levels of activity. The abdominal aorta is normal in caliber. There is modest atherosclerotic calcification in the distal aorta and proximal iliac arteries. There is no evidence of ascites or pneumoperitoneum. Abdominal and pelvic lymph nodes demonstrate generally physiologic levels of activity. The small bowel demonstrates normal levels of activity. The colon demonstrates a generally physiologic distribution of activity. There is an increased activity in the distal ileum and cecum and ascending colon, probably inflammatory. The prostate gland measures approximately 4 cm transverse dimension and demonstrates physiologic levels of activity

The included portions of the skeleton demonstrate normal physiologic levels of activity.

IMPRESSION:

1. The PET CT examination demonstrates a physiologic distribution of activity in the thorax. The examination demonstrates no abnormal activity in the esophagus and no trace of the extensive adenopathy seen on the earlier examination.
2. The examination demonstrates a physiologic distribution of activity in the abdomen and pelvis.
3. The examination demonstrates a physiologic distribution of activity in the included portions of the head and neck.
4. The examination demonstrates a physiologic distribution of activity in the included portions of the skeleton and extremities.

PACS Images

Show images for PET Esophageal cancer restaging

Study Result

EXAM: Whole-body PET CT scan.

+0

HISTORY: Esophageal cancer diagnosed in [REDACTED] Restaging.

COMPARISON [REDACTED] +28

PROCEDURE: The patient was injected with 14.4 millicuries of F-18 FDG and allowed to rest in a quiet room for approximately 1 hour. The patient was then placed on the scanning table and a whole body scan performed from the skull base through the level of the thighs in conjunction with a spiral CT scan from the skull base through the level of the thighs utilized both for attenuation correction and also for the creation of a spatially registered CT examination for PET / CT fusion. The CT scan, PET scan and fused PET/CT scan were presented for evaluation in axial, sagittal and coronal planes. Additional images including a rotating maximum intensity projection image of the PET scan were provided as required. (The noncontrast CT

[page 15 of 19]
[REDACTED]

images utilized for fusion with the PET images to create the PET / CT images are not of diagnostic quality and are not used to diagnose disease independently of the PET images.) The patient's blood glucose level was 88 milligrams per deciliter.

FINDINGS:

In the head and neck, the included portions of the orbits and paranasal sinuses demonstrate normal levels of activity. The nasopharynx, oropharynx and oral cavity demonstrate normal levels of activity. The larynx and vocal cords demonstrate normal levels of activity. The salivary glands demonstrate normal levels of activity. The thyroid gland demonstrates normal levels of activity. No FDG avid lymph nodes are seen in the neck. There is a chemotherapy infusion port implanted in the right anterior chest wall with subclavian catheter extending into the superior vena cava terminating above the cavoatrial junction.

In the thorax, the lungs are generally well expanded with no evidence of significant infiltrate or consolidation or effusion. No significantly FDG avid nodules are seen within the lung fields. The extensive highly FDG avid adenopathy seen on the prior examination is absent on the current examination. There are calcified nodes in the right hilar region and a few calcified pulmonary nodules compatible with granulomatous disease. The thoracic aorta is normal in caliber. There is no detectable vascular calcification. The heart is normal in size. There is moderately extensive physiologic uptake of FDG within the left ventricular myocardium. There is no significantly elevated activity in the esophagus on the current examination.

In the abdomen and pelvis, the liver demonstrates a typical heterogeneous pattern of activity. The representative SUV max for the liver is 4.2. The spleen is normal in appearance. The stomach is physiologically distended with ingested material and demonstrates normal levels of activity. The pancreas demonstrates normal levels of activity. The adrenal glands demonstrate normal levels of activity. The gallbladder is normally distended and contains no identifiable stones. The kidneys, ureters and urinary bladder demonstrate physiologic levels of activity. The abdominal aorta is normal in caliber. There is modest atherosclerotic calcification in the distal aorta and proximal iliac arteries. There is no evidence of ascites or pneumoperitoneum. Abdominal and pelvic lymph nodes demonstrate generally physiologic levels of activity. The small bowel demonstrates normal levels of activity. The colon demonstrates a generally physiologic distribution of activity. There is an increased activity in the distal ileum and cecum and ascending colon, probably inflammatory. The prostate gland measures approximately 4 cm transverse dimension and demonstrates physiologic levels of activity.

The included portions of the skeleton demonstrate normal physiologic levels of activity.

IMPRESSION:

1. The PET CT examination demonstrates a physiologic distribution of activity in the thorax. The examination demonstrates no abnormal activity in the esophagus and no trace of the extensive adenopathy seen on the earlier examination.

[page 16 of 19]
2. The examination demonstrates a physiologic distribution of activity in the abdomen and pelvis.

3. The examination demonstrates a physiologic distribution of activity in the included portions of the head and neck.

4. The examination demonstrates a physiologic distribution of activity in the included portions of the skeleton and extremities.

Signed by

Signed	Date/Time	Phone	Pager
--------	-----------	-------	-------

Exam Information

+1710

Status	Exam Begun	Exam Ended
--------	------------	------------

External Results Report

+1707

Encounter

+1707

Open External Results Report

View Encounter

Order Report

PET Esophageal cancer restaging (Order

+1707

Reprint Order Requisition

PET Esophageal cancer restaging (Order

+1707

PACS Images

Show Images for PET Esophageal cancer restaging

[page 17 of 19]
CT Abdomen pelvis withOUT contrast

Order # [REDACTED]

Reason For Exam

MAL NEO ESOPHAGUS NOS

Interpretation Summary

CT chest, abdomen and pelvis without contrast

HISTORY: Malignant neoplasm of the esophagus.

Procedures: 3 mm contiguous axial images were obtained through the abdomen and pelvis without the use of intravenous or oral contrast. Coronal reformatted images were also created and reviewed.

Comparison: [REDACTED] +114

Findings: Evaluation of the soft tissues is limited without the use of intravenous or oral contrast.

Chest CT: There is no axillary lymphadenopathy. There is a right IJ central line with the tip in the superior vena cava. There is redemonstration of calcified right hilar and mediastinal lymph nodes. There is no mediastinal lymphadenopathy. There is redemonstration of surgical clips along the anterior left aspect of the superior mediastinum. There is redemonstration and stable appearance of a 2 cm x 1 cm soft tissue nodule in the left lateral aspect of the anterior mediastinum. No new soft tissue masses are identified. There is atherosclerotic plaque in the coronary arteries. There is no pericardial effusion. Lung windows demonstrate no pneumothorax or lobar consolidation. There is no pulmonary mass identified. Calcified granulomata are again noted. The trachea and mainstem bronchi are patent.

CT abdomen and pelvis: The liver, gallbladder, spleen, pancreas and adrenal glands appear within normal limits. The kidneys are symmetric in size. There is no radiodense renal stone, hydronephrosis or apparent renal mass. The stomach and unopacified small bowel appear within normal limits. The appendix is not inflamed. The colon is within normal limits. The urinary bladder, prostate gland and rectum appear within normal limits. There is no free air or free fluid in the abdomen or pelvis. There are multiple periaortic lymph nodes which are mildly enlarged, these do not appear changed compared to the earlier examination. There is no new soft tissue mass identified..

Bone windows demonstrate no evidence of acute fracture. There are degenerative findings in the spine.

+114

Impressions: Compared to [REDACTED] there is stable appearance of postsurgical change in the anterior left mediastinum. There is stable appearance of small soft tissue nodules in the left aspect of the anterior superior mediastinum as before, there is also a stable appearance of mild lymphadenopathy in the periaortic distribution.

[page 18 of 19]
[REDACTED]

There is no new lymphadenopathy or suspicious mass identified.

Atherosclerosis and evidence of prior granulomatosis.

Right IJ central line with the tip in the superior vena cava.

PACS Images

Show images for CT Abdomen pelvis withOUT contrast

Study Result

CT chest, abdomen and pelvis without contrast

HISTORY: Malignant neoplasm of the esophagus.

Procedures: 3 mm contiguous axial images were obtained through the abdomen and pelvis without the use of intravenous or oral contrast. Coronal reformatted images were also created and reviewed.

Comparison: [REDACTED] +114

Findings: Evaluation of the soft tissues is limited without the use of intravenous or oral contrast.

Chest CT: There is no axillary lymphadenopathy. There is a right IJ central line with the tip in the superior vena cava. There is redemonstration of calcified right hilar and mediastinal lymph nodes. There is no mediastinal lymphadenopathy. There is redemonstration of surgical clips along the anterior left aspect of the superior mediastinum. There is redemonstration and stable appearance of a 2 cm x 1 cm soft tissue nodule in the left lateral aspect of the anterior mediastinum. No new soft tissue masses are identified. There is atherosclerotic plaque in the coronary arteries. There is no pericardial effusion. Lung windows demonstrate no pneumothorax or lobar consolidation. There is no pulmonary mass identified. Calcified granulomata are again noted. The trachea and mainstem bronchi are patent.

CT abdomen and pelvis: The liver, gallbladder, spleen, pancreas and adrenal glands appear within normal limits. The kidneys are symmetric in size. There is no radiodense renal stone, hydronephrosis or apparent renal mass. The stomach and unopacified small bowel appear within normal limits. The appendix is not inflamed. The colon is within normal limits. The urinary bladder, prostate gland and rectum appear within normal limits. There is no free air or free fluid in the abdomen or pelvis. There are multiple periaortic lymph nodes which are mildly enlarged, these do not appear changed compared to the earlier examination. There is no new soft tissue mass identified..

Bone windows demonstrate no evidence of acute fracture. There are degenerative findings in the spine. +114

Impressions: Compared to [REDACTED] there is stable appearance of postsurgical change in the anterior left mediastinum. There is stable appearance of small soft tissue nodules in the left aspect of the anterior superior mediastinum as before, there is also a stable

[page 19 of 19]
[REDACTED]

appearance of mild lymphadenopathy in the periaortic distribution.

There is no new lymphadenopathy or suspicious mass identified.

Atherosclerosis and evidence of prior granulomatosis.

Right IJ central line with the tip in the superior vena cava.

Signed by

Signed

Date/Time

Phone

Pager

[REDACTED]

Exam Information

+175

Status

Exam
Begun

Exam
Ended

[REDACTED]

External Results Report

+174

Encounter

+174

Open External Results Report

View Encounter

Order Report

CT Abdomen pelvis withOUT contrast (Order

[REDACTED] +174

Reprint Order Requisition

CT Abdomen pelvis withOUT contrast (Order

[REDACTED] +174

PACS Images

Show images for CT Abdomen pelvis withOUT contrast

Source: NCI Genomic Data Commons file b541bba3-505f-4f7a-9ea7-eed87c96d64a (ER0376 ER-B0AT Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).